Somatic mutation profile of tumor specimen C3L-02615-02 (aliquot CPT0228340007) from CPTAC case C3L-02615, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 80.6 years (29,454 days).
Specimen C3L-02615-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43444f26-2168-4ad6-bd5f-e7cef2c43426.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02615-31 (Blood Derived Normal), aliquot CPT0228430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/692ba86a-dc60-4080-8d9d-851c16b21116

The open-access MAF lists 7,508 somatic variants for this specimen: 4,832 protein-altering or splice-affecting, 2,407 silent, 269 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4,408, Silent 2,407, Nonsense Mutation 290, Intron 166, Splice Region 57, Splice Site 37, 3'UTR 24, RNA 23, Frame Shift Del 20, 3'Flank 20, 5'Flank 19, 5'UTR 17.

Variants (750 of 7,508; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs138157885, CM074663; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ALDOB | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 59/299 reads (20%) | catalogued as rs118204428, CM950061; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AMHR2 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 184/527 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs137853104, CM016199, COSV99143488; ClinVar: pathogenic; called by muse, mutect2, varscan2
- B2M | c.68-1G>A p.X23_splice | Splice Site (SNP) | VAF 61/176 reads (35%) | hotspot (GDC flag); catalogued as COSV62563163, COSV62563826; called by muse, mutect2, varscan2
- BRAF | c.1876G>A p.E626K (on ENST00000288602 / NM_001374244.1; = p.E586K on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs121913340, COSV56082407, COSV56115488; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.2590C>T p.Q864* | Nonsense Mutation (SNP) | VAF 28/205 reads (14%) | catalogued as rs1060502414; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CC2D2A | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 35/280 reads (13%) | catalogued as rs781252161, COSV104432586; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 149/469 reads (32%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- CFTR | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs397508342, CM024683, COSV50043054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CFTR | c.3353C>T p.S1118F | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs146521846, CM983576, CM993866; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD3 | c.2953C>T p.R985W | Missense Mutation (SNP) | VAF 145/317 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555611722; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CHD8 | c.3733C>T p.R1245* (on ENST00000646647 / NM_001170629.2; = p.R966* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 82/306 reads (27%) | catalogued as rs886041884; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL6A2 | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 59/394 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs267606750, CM020671; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYP2C8 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 63/286 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV64876179; called by muse, varscan2
- CYP4F22 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 53/315 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.35); catalogued as rs369811073; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH8 | c.7981C>T p.R2661* | Nonsense Mutation (SNP) | VAF 64/368 reads (17%) | catalogued as rs149070832; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 124/365 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs199473480, CM043018; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- MYH7 | c.2686G>A p.D896N | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs606231340; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.5660C>T p.P1887L | Missense Mutation (SNP) | VAF 77/302 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199606180, CM004274, COSV68684795; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RBP3 | c.3238G>A p.D1080N | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs146150511, CM091804; ClinVar: pathogenic; called by muse, varscan2
- RIPPLY2 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 62/255 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100859440, COSV63746041; called by muse, mutect2, varscan2
- SCN1A | c.4412C>T p.S1471F (on ENST00000303395 / NM_001202435.3; = p.S1460F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/204 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs794726809, CM1511240; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC22A5 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 71/261 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72552735, CM991138, COSV55374912; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC25A19 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 118/528 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1555604541; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMPRSS6 | c.1768C>T p.R590* | Nonsense Mutation (SNP) | VAF 157/624 reads (25%) | catalogued as rs137853123, CM083568, COSV60977683; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 170/395 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2M | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 69/282 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778604418, COSV59383298; called by muse, mutect2, varscan2
- A2ML1 | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 153/474 reads (32%) | catalogued as rs757780027; called by muse, mutect2, varscan2
- A2ML1 | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 67/286 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV55288184; called by muse, mutect2, varscan2
- A2ML1 | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 154/476 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs780281065, COSV55287724; called by muse, mutect2, varscan2
- AAR2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 115/402 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.077); catalogued as rs1364161394; called by muse, mutect2, varscan2
- AARS1 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 118/510 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302363015, COSV99933223; called by muse, mutect2, varscan2
- ABCA4 | c.5915G>A p.G1972E | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100933161, COSV64672488; called by muse, mutect2, varscan2
- ABCA4 | c.5196C>T p.I1732= | Splice Region (SNP) | VAF 52/176 reads (30%) | catalogued as rs940382049, COSV64677960; called by muse, varscan2
- ABCA7 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 89/404 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54036189; called by muse, mutect2, varscan2
- ABCB8 | c.2143C>T p.P715S (on ENST00000297504 / NM_001282291.2; = p.P698S on NM_007188.5) | Missense Mutation (SNP) | VAF 185/678 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs764347464, COSV99874279; called by muse, mutect2, varscan2
- ABCC10 | c.1484G>A p.R495Q (on ENST00000372530 / NM_001198934.2; = p.R452Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/387 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs767570542, COSV55091253, COSV55092526; called by muse, mutect2, varscan2
- ABCC11 | c.3540G>A p.G1180= | Splice Region (SNP) | VAF 57/284 reads (20%) | catalogued as COSV100750948; called by muse, mutect2, varscan2
- ABCC9 | c.2080C>T p.R694* | Nonsense Mutation (SNP) | VAF 40/268 reads (15%) | catalogued as rs1194330942, COSV53966814; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCG4 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 82/455 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1228303791, COSV56643499; called by muse, mutect2, varscan2
- ABI3BP | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs1277852629; called by muse, mutect2, varscan2
- ABO | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 93/403 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); catalogued as rs939847602, COSV71743668; called by muse, mutect2, varscan2
- ABT1 | c.275C>G p.A92G | Missense Mutation (SNP) | VAF 64/241 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs374428829; called by muse, mutect2, varscan2
- ACAD10 | c.1571G>A p.G524E | Missense Mutation (SNP) | VAF 53/396 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58156243; called by muse, mutect2, varscan2
- ACAP1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 192/441 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV50138244; called by muse, mutect2, varscan2
- ACE | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 115/518 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs77294580; called by muse, mutect2, varscan2
- ACSF3 | c.1486C>T p.H496Y | Missense Mutation (SNP) | VAF 91/332 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs529097844; called by muse, varscan2
- ACSL6 | c.1625G>A p.G542E (on ENST00000379240; = p.G567E on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/314 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57299413; called by muse, mutect2, varscan2
- ACSM1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 80/308 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV54633527; called by muse, mutect2, varscan2
- ACSM1 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as rs905851561, COSV54632777; called by muse, varscan2
- ACSM1 | c.1054C>T p.Q352* | Nonsense Mutation (SNP) | VAF 98/434 reads (23%) | catalogued as rs565501213; called by muse, varscan2
- ACSM2B | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 79/348 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as rs374731787; called by muse, mutect2, varscan2
- ACSS2 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 114/399 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs763781277, COSV53624046; called by muse, mutect2, varscan2
- ACTB | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 61/616 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1411316425, COSV100079919; called by muse, mutect2, varscan2
- ACTBL2 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 203/569 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); catalogued as COSV70661161; called by muse, mutect2, varscan2
- ACTL6B | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 86/341 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.345); catalogued as COSV50520836; called by muse, mutect2, varscan2
- ACTN2 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 60/403 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs767763639, COSV63971679; called by muse, mutect2, varscan2
- ADAD2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 198/719 reads (28%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.086); catalogued as rs1015077091; called by muse, mutect2, varscan2
- ADAM11 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 92/490 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV52349480; called by muse, mutect2, varscan2
- ADAM17 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.611); catalogued as rs1052300902; called by muse, mutect2
- ADAM18 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 86/363 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55847619; called by muse, mutect2, varscan2
- ADAM18 | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 66/260 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs865870698, COSV55844130; called by muse, mutect2, varscan2
- ADAM2 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 65/316 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.055); catalogued as rs1486484687, COSV55858669; called by muse, mutect2, varscan2
- ADAM21 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV50789964; called by muse, mutect2, varscan2
- ADAM28 | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs866455551; called by muse, varscan2
- ADAM29 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 137/402 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV63668085; called by muse, mutect2, varscan2
- ADAM29 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 45/365 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV63663811; called by muse, mutect2, varscan2
- ADAM29 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 46/381 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.029); catalogued as COSV63666985; called by muse, mutect2, varscan2
- ADAM7 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 60/301 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs940085461, COSV51538068; called by muse, mutect2, varscan2
- ADAM7 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 99/443 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51538725; called by muse, mutect2, varscan2
- ADAM7 | c.2197C>T p.H733Y | Missense Mutation (SNP) | VAF 68/282 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs867658404, COSV51536214; called by muse, mutect2, varscan2
- ADAMTS10 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 84/383 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV54352128; called by muse, varscan2
- ADAMTS16 | c.2785C>T p.P929S | Missense Mutation (SNP) | VAF 140/395 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs1392385481, COSV99943616; called by muse, mutect2, varscan2
- ADAMTS18 | c.2819G>A p.W940* | Nonsense Mutation (SNP) | VAF 92/344 reads (27%) | catalogued as COSV51399520; called by muse, mutect2, varscan2
- ADAMTS18 | c.2436C>A p.F812L | Missense Mutation (SNP) | VAF 74/415 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV51411170; called by muse, mutect2, varscan2
- ADAMTS19 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs774449550, COSV50735670, COSV50774384; called by muse, mutect2, varscan2
- ADAMTS2 | c.2465C>T p.P822L | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as rs777107579; called by muse, mutect2, varscan2
- ADAMTS3 | c.2927G>A p.S976N | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs1292408222; called by muse, mutect2, varscan2
- ADAMTS6 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs542293343; called by muse, mutect2, varscan2
- ADARB2 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 110/508 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.25); catalogued as rs554622151; called by muse, varscan2
- ADCY1 | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 90/499 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs372552814; called by muse, varscan2
- ADCY10 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV100896842; called by muse, mutect2, varscan2
- ADCY4 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 116/391 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); catalogued as COSV99064150; called by muse, varscan2
- ADCY5 | c.3637G>A p.G1213S | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774848359, COSV59197832; called by muse, mutect2, varscan2
- ADGB | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV58860456; called by muse, mutect2, varscan2
- ADGB | c.4594C>T p.R1532* | Nonsense Mutation (SNP) | VAF 71/281 reads (25%) | catalogued as COSV58847400; called by muse, mutect2, varscan2
- ADGRB3 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs766735540, COSV65381042; called by muse, mutect2, varscan2
- ADGRB3 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 62/324 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs549905059, COSV65389273, COSV65401985; called by muse, mutect2
- ADGRB3 | c.3532C>T p.P1178S | Missense Mutation (SNP) | VAF 77/312 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV53238942, COSV53247980; called by muse, mutect2, varscan2
- ADGRB3 | c.3685G>A p.G1229R | Missense Mutation (SNP) | VAF 88/301 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV53239383; called by muse, mutect2, varscan2
- ADGRD1 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 62/510 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267603379; called by muse, varscan2
- ADGRE1 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs143078439; called by muse, varscan2
- ADGRE3 | c.1937G>A p.G646E | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV53733893; called by muse, varscan2
- ADGRF2 | c.350C>T p.S117F (on ENST00000296862 / NM_001368115.2; = p.S49F on NM_153839.7) | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs745398972, COSV57292632; called by muse, mutect2, varscan2
- ADGRF2 | c.985G>A p.E329K (on ENST00000296862 / NM_001368115.2; = p.E261K on NM_153839.7) | Missense Mutation (SNP) | VAF 62/322 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as rs764110566, COSV57286334; called by muse, mutect2, varscan2
- ADGRG4 | c.3805C>T p.P1269S | Missense Mutation (SNP) | VAF 124/260 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99055338; called by muse, mutect2, varscan2
- ADGRG5 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 104/327 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV61082658; called by muse, mutect2, varscan2
- ADGRL2 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54669811; called by muse, mutect2, varscan2
- ADGRL2 | c.1139G>A p.W380* | Nonsense Mutation (SNP) | VAF 72/320 reads (23%) | catalogued as COSV99590813; called by muse, mutect2, varscan2
- ADGRV1 | c.1259T>C p.V420A | Missense Mutation (SNP) | VAF 80/278 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV67991302; called by muse, mutect2, varscan2
- ADGRV1 | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as COSV101316688; called by muse, mutect2, varscan2
- ADH1A | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759074518, COSV52924951, COSV52925007; called by muse, mutect2, varscan2
- ADH1B | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV100520873; called by muse, mutect2, varscan2
- ADH6 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52956526; called by muse, mutect2, varscan2
- ADRA1A | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 203/625 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); catalogued as rs908462360; called by muse, mutect2, varscan2
- AFF3 | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 269/629 reads (43%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.642); catalogued as COSV57866286; called by muse, mutect2, varscan2
- AFM | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.192); catalogued as COSV56919802; called by muse, mutect2, varscan2
- AFM | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as rs781660797, COSV56920526, COSV56922687; called by muse, mutect2, varscan2
- AGBL1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 119/405 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs1195765001, COSV101222744; called by muse, mutect2, varscan2
- AGMO | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 45/288 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV61105498; called by muse, mutect2, varscan2
- AGPAT4 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 100/350 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV57251649; called by muse, mutect2, varscan2
- AGPAT4 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 133/476 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs141441479; called by muse, mutect2, varscan2
- AGT | c.314T>C p.M105T | Missense Mutation (SNP) | VAF 70/462 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs933260912; called by muse, mutect2, varscan2
- AGXT2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 80/456 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs200627716; called by muse, mutect2, varscan2
- AHNAK | c.6245C>T p.P2082L | Missense Mutation (SNP) | VAF 167/568 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs762345517; called by muse, mutect2, varscan2
- AHNAK2 | c.10937C>T p.P3646L | Missense Mutation (SNP) | VAF 54/423 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs372014641; called by muse, mutect2, varscan2
- AICDA | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 94/508 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386378825; called by muse, mutect2, varscan2
- AIFM3 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 112/429 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV58999279; called by muse, mutect2, varscan2
- AIRE | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 102/351 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); catalogued as rs55840791, COSV99381577; called by muse, mutect2, varscan2
- AJAP1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 119/520 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs1362035936, COSV65452111; called by muse, mutect2, varscan2
- AKNA | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 128/570 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs755961862; called by muse, mutect2, varscan2
- AKR1B15 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 72/737 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV71152829; called by muse, mutect2, varscan2
- AL645922.1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 134/517 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.078); catalogued as rs139113913, COSV54963040; called by muse, mutect2, varscan2
- AL669918.1 | c.2465G>A p.R822K | Missense Mutation (SNP) | VAF 62/259 reads (24%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.023); catalogued as COSV71270890; called by muse, mutect2, varscan2
- ALB | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.59); catalogued as rs1445148767, COSV55738215; called by muse, mutect2, varscan2
- ALB | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 71/255 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs78575701, CM984718, COSV104405337, COSV55736801, COSV55738814; ClinVar: not provided; called by muse, mutect2, varscan2
- ALG14 | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 81/257 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs773910321; called by muse, mutect2, varscan2
- ALPK2 | c.5698T>C p.F1900L | Missense Mutation (SNP) | VAF 97/263 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1042694035; called by muse, mutect2, varscan2
- ALPL | c.976G>A p.G326S | Missense Mutation (SNP) | VAF 52/462 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM020621; called by muse, mutect2, varscan2
- ALPP | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 72/654 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV67396310; called by muse, mutect2, varscan2
- AMBN | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.286); catalogued as COSV59825505, COSV59825826; called by muse, mutect2, varscan2
- AMBRA1 | c.2746C>T p.P916S (on ENST00000458649 / NM_001367468.1; = p.P826S on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 118/498 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.3); catalogued as rs1482583665, COSV54053338; called by muse, mutect2, varscan2
- AMER3 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 70/662 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV58466791; called by muse, mutect2, varscan2
- AMPD1 | c.2028G>A p.M676I | Missense Mutation (SNP) | VAF 64/275 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV62415536; called by muse, mutect2, varscan2
- AMY2A | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 56/747 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs879420983, COSV70214849; called by muse, mutect2
- ANHX | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 240/593 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1271810788; called by muse, mutect2, varscan2
- ANK2 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 84/252 reads (33%) | catalogued as rs146907003, COSV52159416; called by muse, mutect2, varscan2
- ANK3 | c.11899A>C p.T3967P | Missense Mutation (SNP) | VAF 82/724 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs749389112; called by mutect2, varscan2
- ANK3 | c.9157G>A p.E3053K | Missense Mutation (SNP) | VAF 125/481 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV99781717; called by muse, mutect2, varscan2
- ANK3 | c.8087C>T p.S2696L | Missense Mutation (SNP) | VAF 92/397 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); catalogued as rs776042210; called by muse, mutect2, varscan2
- ANK3 | c.6695G>A p.R2232Q | Missense Mutation (SNP) | VAF 97/308 reads (31%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.045); catalogued as rs770107349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.3455G>A p.G1152E (on ENST00000280772 / NM_001320874.2; = p.G286E on NM_001149.3) | Missense Mutation (SNP) | VAF 97/408 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55045770, COSV99778098; called by muse, mutect2, varscan2
- ANK3 | c.2632G>A p.G878R (on ENST00000280772 / NM_001320874.2; = p.G12R on NM_001149.3) | Missense Mutation (SNP) | VAF 74/282 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770736443, COSV55062433; called by muse, varscan2
- ANK3 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 102/436 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55048999; called by muse, varscan2
- ANKEF1 | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 105/282 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1350582471; called by muse, mutect2, varscan2
- ANKK1 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 64/423 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs199582150; called by muse, mutect2, varscan2
- ANKRD2 | c.429C>T p.I143= | Splice Region (SNP) | VAF 88/417 reads (21%) | catalogued as COSV53967782; called by muse, mutect2, varscan2
- ANKRD30A | c.565G>A p.E189K (on ENST00000611781; = p.E133K on NM_052997.2) | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100653302; called by muse, mutect2, varscan2
- ANKRD30A | c.751C>T p.H251Y (on ENST00000611781; = p.H195Y on NM_052997.2) | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV100652838; called by muse, mutect2, varscan2
- ANKRD30A | c.3328G>A p.E1110K (on ENST00000611781; = p.E1054K on NM_052997.2) | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs267602485, COSV64603763; called by muse, mutect2, varscan2
- ANKRD30A | c.4162G>A p.E1388K (on ENST00000611781; = p.E1332K on NM_052997.2) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs1332093611, COSV64607257; called by muse, mutect2, varscan2
- ANKRD31 | c.308G>C p.R103P | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV57157133; called by mutect2, varscan2
- ANKRD36 | c.2135C>T p.S712F | Missense Mutation (SNP) | VAF 85/255 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1219322155; called by muse, mutect2, varscan2
- ANKRD55 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 113/273 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs867180353, COSV61946887; called by muse, mutect2, varscan2
- ANKS1B | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 44/357 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1396582968; called by muse, mutect2, varscan2
- ANKS1B | c.1103T>C p.L368P | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV61366378; called by muse, varscan2
- ANKS3 | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 103/440 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as rs755830521; called by muse, mutect2, varscan2
- ANLN | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 137/306 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as rs761217773; called by muse, mutect2, varscan2
- ANPEP | c.2449C>T p.R817* | Nonsense Mutation (SNP) | VAF 134/503 reads (27%) | catalogued as rs375864084; called by muse, varscan2
- ANXA3 | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 70/254 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs539172460, COSV53713158, COSV99363589; called by muse, mutect2, varscan2
- AP1B1 | c.2543C>T p.A848V | Missense Mutation (SNP) | VAF 67/373 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as rs542971487; called by muse, mutect2, varscan2
- APBB2 | c.1030C>T p.P344S (on ENST00000295974 / NM_001166050.2; = p.P345S on NM_004307.2) | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99924219; called by muse, mutect2, varscan2
- APOB | c.7601G>A p.R2534Q | Missense Mutation (SNP) | VAF 47/540 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as rs866435648, COSV51948682; called by muse, mutect2
- APOB | c.5324G>A p.S1775N | Missense Mutation (SNP) | VAF 38/447 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as COSV51944319; called by muse, mutect2
- APOB | c.2779C>A p.P927T | Missense Mutation (SNP) | VAF 156/384 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs757511363; called by muse, mutect2, varscan2
- ARGFX | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as rs1196486208, COSV57681687; called by muse, mutect2, varscan2
- ARHGAP15 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54492030; called by muse, mutect2, varscan2
- ARHGAP22 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 114/408 reads (28%) | SIFT tolerated (0.99); PolyPhen benign (0.02); catalogued as rs1027250027, COSV50945462; called by muse, mutect2, varscan2
- ARHGAP27 | c.1975G>A p.G659S (on ENST00000428638 / NM_001282290.1; = p.G318S on NM_199282.3) | Missense Mutation (SNP) | VAF 126/557 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1277915206; called by muse, mutect2, varscan2
- ARHGAP29 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53109976; called by muse, mutect2, varscan2
- ARHGAP29 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1020434901; called by muse, mutect2, varscan2
- ARHGAP4 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 113/196 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as rs782598414, COSV100604173; called by muse, mutect2, varscan2
- ARHGAP44 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV52390417, COSV52392602; called by muse, mutect2, varscan2
- ARHGEF10L | c.3331G>A p.G1111R | Missense Mutation (SNP) | VAF 61/423 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770589299, COSV99393522; called by muse, mutect2, varscan2
- ARHGEF11 | c.2728C>T p.R910W | Missense Mutation (SNP) | VAF 100/301 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs751287525; called by muse, varscan2
- ARHGEF16 | c.53G>C p.R18P | Missense Mutation (SNP) | VAF 182/591 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs1038152955; called by muse, mutect2, varscan2
- ARHGEF2 | c.398C>T p.S133F (on ENST00000361247 / NM_001162383.2; = p.S106F on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 136/388 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV58107243; called by muse, mutect2, varscan2
- ARID1B | c.6478C>T p.Q2160* | Nonsense Mutation (SNP) | VAF 127/523 reads (24%) | catalogued as rs1554238125, COSV51648834; called by muse, mutect2, varscan2
- ARID2 | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 89/275 reads (32%) | catalogued as COSV57595668; called by muse, mutect2, varscan2
- ARMC3 | c.1417C>T p.R473W | Missense Mutation (SNP) | VAF 71/259 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755004893, COSV99957595; called by muse, mutect2, varscan2
- ARMC4 | c.2258G>A p.R753Q | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs760325470, COSV100536722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARMC4 | c.1600C>T p.L534F | Missense Mutation (SNP) | VAF 67/337 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs1456549323; called by muse, mutect2, varscan2
- ARMC4 | c.177G>A p.W59* | Nonsense Mutation (SNP) | VAF 65/353 reads (18%) | catalogued as COSV59466892; called by muse, mutect2, varscan2
- ARNTL2 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 106/353 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779219673, COSV99667759; called by muse, mutect2, varscan2
- ARSF | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 141/275 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63839279; called by muse, mutect2, varscan2
- ART3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 101/307 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61914722; called by muse, mutect2, varscan2
- ART4 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 112/467 reads (24%) | catalogued as rs770694825, COSV57450945; called by muse, mutect2
- ASB1 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 241/500 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs552809178; called by muse, mutect2, varscan2
- ASB4 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 82/377 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.101); catalogued as COSV99987218, COSV99987246; called by muse, mutect2, varscan2
- ASIC2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 124/498 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs749146881, COSV63293686; called by muse, varscan2
- ASIC5 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 87/280 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs200759770; called by muse, mutect2, varscan2
- ASMTL | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 169/523 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.089); catalogued as rs1299255795, COSV101187904, COSV101187979; called by muse, mutect2, varscan2
- ASPH | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 95/395 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770489156; called by muse, mutect2, varscan2
- ASTL | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 135/328 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as rs748161965, COSV60903543; called by muse, mutect2, varscan2
- ASTN1 | c.3700G>A p.G1234R | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.158); catalogued as COSV100706493; called by muse, mutect2, varscan2
- ASTN2 | c.1331C>T p.S444F (on ENST00000313400 / NM_001365069.1; = p.S393F on NM_014010.5) | Missense Mutation (SNP) | VAF 91/411 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs866109686, COSV57764562; called by muse, mutect2, varscan2
- ASXL2 | c.3445C>T p.R1149C | Missense Mutation (SNP) | VAF 42/387 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs377352572, COSV55454592; called by muse, mutect2, varscan2
- ASZ1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 122/429 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1343852598, COSV52914933; called by muse, mutect2, varscan2
- ATAD3B | c.827C>T p.A276V (on ENST00000308647; = p.A382V on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/519 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as rs1368220154; called by muse, mutect2, varscan2
- ATAD5 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 89/375 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs373509661, COSV58971918; called by muse, mutect2, varscan2
- ATM | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs375091571; called by muse, mutect2, varscan2
- ATP10B | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 93/326 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as rs368181743; called by muse, mutect2, varscan2
- ATP13A5 | c.3089G>A p.G1030E | Missense Mutation (SNP) | VAF 98/403 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.261); catalogued as rs372940991, COSV100665430; called by muse, mutect2, varscan2
- ATP1A2 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 100/333 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.19); catalogued as rs765021457, COSV63403673; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 135/398 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.405); catalogued as rs766354816; called by muse, mutect2, varscan2
- ATP6V1C2 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 51/437 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as COSV55360866; called by muse, mutect2, varscan2
- ATP6V1H | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs576327305, COSV62218441; called by muse, mutect2, varscan2
- ATP8B4 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752810289, COSV52718864; called by muse, mutect2, varscan2
- ATR | c.7136G>A p.W2379* | Nonsense Mutation (SNP) | VAF 89/333 reads (27%) | catalogued as COSV63384236; called by muse, mutect2, varscan2
- ATXN1 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 140/516 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as rs144862299; called by muse, mutect2, varscan2
- AVPR1B | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 84/331 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs897408338; called by muse, mutect2, varscan2
- AXDND1 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 80/275 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs192778181, COSV62648232; called by muse, mutect2, varscan2
- B4GALNT4 | c.2258G>A p.R753Q | Missense Mutation (SNP) | VAF 113/333 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.818); catalogued as rs1043523402; called by muse, mutect2, varscan2
- BAAT | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 122/464 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV52287231; called by muse, varscan2
- BACH2 | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 111/493 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs750705861, COSV57599719; called by muse, mutect2
- BACH2 | c.2182C>T p.R728W | Missense Mutation (SNP) | VAF 119/459 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs780883403, COSV57591239; called by muse, mutect2, varscan2
- BCAS1 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 102/403 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.494); catalogued as rs1027786237, COSV65086011; called by muse, mutect2, varscan2
- BCAS3 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 80/357 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1331743647, COSV66773096; called by muse, mutect2, varscan2
- BCL10 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1320962678; called by muse, mutect2, varscan2
- BCL9 | c.2807C>T p.S936F | Missense Mutation (SNP) | VAF 44/423 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99325357; called by muse, mutect2, varscan2
- BCR | c.1945C>T p.R649C | Missense Mutation (SNP) | VAF 65/313 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778805924; called by muse, mutect2, varscan2
- BEX5 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 88/197 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV61328416; called by muse, mutect2, varscan2
- BHMT2 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as rs1381382263; called by muse, mutect2, varscan2
- BLM | c.4049C>T p.T1350I | Missense Mutation (SNP) | VAF 72/382 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs1052029776; called by muse, varscan2
- BMP5 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 73/321 reads (23%) | catalogued as rs1396089139, COSV63701194; called by muse, mutect2, varscan2
- BMPER | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1434938264, COSV99779747; called by mutect2, varscan2
- BMT2 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 69/244 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV51777698; called by muse, mutect2, varscan2
- BNC1 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 97/452 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1243219399, COSV61758887; called by muse, mutect2, varscan2
- BNC1 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 155/512 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV61759379; called by muse, mutect2, varscan2
- BPIFA1 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 116/530 reads (22%) | catalogued as rs1337730552, COSV62825130, COSV62825351; called by muse, mutect2, varscan2
- BPIFA1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 68/258 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV62824268; called by muse, varscan2
- BPIFB3 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 124/509 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64957161; called by muse, mutect2, varscan2
- BRCA1 | c.4976C>T p.P1659L | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100523516, COSV58803344; called by muse, varscan2
- BRCA1 | c.2935C>T p.R979C | Missense Mutation (SNP) | VAF 147/381 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs80356970, COSV58795841; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BRD4 | c.3841C>T p.R1281W | Missense Mutation (SNP) | VAF 128/521 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs754054879; called by muse, mutect2, varscan2
- BRINP3 | c.1788G>A p.W596* | Nonsense Mutation (SNP) | VAF 41/363 reads (11%) | catalogued as COSV100819596; called by muse, mutect2
- BRINP3 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 92/260 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV66515410, COSV66528573; called by muse, mutect2, varscan2
- BRINP3 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 91/326 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867393057, COSV100818417, COSV100819618; called by muse, mutect2, varscan2
- BRPF3 | c.3335C>T p.P1112L | Missense Mutation (SNP) | VAF 136/490 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1452180112; called by muse, mutect2, varscan2
- BSG | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV61077122; called by muse, mutect2, varscan2
- BSN | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 180/743 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV56516802; called by muse, mutect2, varscan2
- BSN | c.2710G>A p.G904S | Missense Mutation (SNP) | VAF 130/574 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.132); catalogued as rs766539897; called by muse, mutect2, varscan2
- BTBD16 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 86/336 reads (26%) | catalogued as COSV53263787; called by muse, mutect2, varscan2
- BTBD7 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 83/566 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58286598; called by muse, mutect2, varscan2
- BTBD8 | c.1825G>A p.E609K (on ENST00000636805 / NM_001376131.1; = p.E96K on NM_015237.4) | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.891); catalogued as COSV64883950; called by muse, mutect2, varscan2
- BTBD8 | c.3608C>T p.S1203L (on ENST00000636805 / NM_001376131.1; = p.S690L on NM_015237.4) | Missense Mutation (SNP) | VAF 50/317 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1040167764; called by muse, mutect2, varscan2
- BTC | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs376806249; called by muse, mutect2, varscan2
- C12orf50 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 36/322 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV53893420; called by muse, mutect2, varscan2
- C16orf54 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 176/691 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.104); catalogued as rs1423868141, COSV61477274; called by muse, mutect2, varscan2
- C19orf67 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 111/585 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs762004012; called by muse, mutect2, varscan2
- C1QL2 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 69/671 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs1558718370; called by muse, mutect2, varscan2
- C1QL2 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 79/775 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV55606459; called by muse, mutect2
- C1RL | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 152/685 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752211597; called by muse, mutect2, varscan2
- C1orf116 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 131/435 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100847953; called by muse, mutect2, varscan2
- C1orf87 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs762612884, COSV64596931; called by muse, mutect2, varscan2
- C1orf94 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 98/483 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV64915824; called by muse, mutect2, varscan2
- C20orf144 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 143/584 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs997208461; called by muse, mutect2, varscan2
- C2CD3 | c.2257C>T p.H753Y | Missense Mutation (SNP) | VAF 102/496 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV58090079; called by muse, mutect2, varscan2
- C2orf16 | c.1394A>G p.K465R | Missense Mutation (SNP) | VAF 183/374 reads (49%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.71); catalogued as COSV71613735; called by muse, mutect2, varscan2
- C2orf16 | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 43/356 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.197); catalogued as rs533405715; called by muse, varscan2
- C3 | c.3940G>A p.E1314K | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV55569722; called by muse, varscan2
- C6 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 144/429 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV54708223; called by muse, mutect2, varscan2
- C6 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 127/365 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV54714318; called by muse, mutect2, varscan2
- C6 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 121/360 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs267600638, COSV54704649; called by muse, mutect2, varscan2
- C6orf201 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 54/253 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV60985132; called by muse, mutect2, varscan2
- C7 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 86/525 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs754622338, COSV57472460; called by muse, mutect2, varscan2
- C7 | c.1973C>T p.S658F | Missense Mutation (SNP) | VAF 66/708 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs866073266, COSV57470115; called by muse, mutect2
- C7 | c.2338G>A p.G780R | Missense Mutation (SNP) | VAF 39/383 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1015278248, COSV57479551; called by muse, mutect2, varscan2
- C8B | c.1095G>A p.M365I | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV64779873; called by muse, mutect2, varscan2
- C8B | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 66/439 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64776600; called by muse, mutect2, varscan2
- C8orf34 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV57401927, COSV57405348; called by muse, mutect2, varscan2
- C9 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 42/412 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV54678438; called by muse, varscan2
- CA10 | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 73/366 reads (20%) | catalogued as rs866323451; called by muse, mutect2, varscan2
- CACNA1A | c.5503G>A p.D1835N | Missense Mutation (SNP) | VAF 65/340 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100801834; called by muse, varscan2
- CACNA1A | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100802491; called by muse, mutect2, varscan2
- CACNA1B | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 71/379 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs1182464278; called by muse, mutect2, varscan2
- CACNA1E | c.2744G>A p.R915K | Missense Mutation (SNP) | VAF 126/431 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.745); catalogued as rs867916859; called by muse, mutect2, varscan2
- CACNA1E | c.4048C>T p.R1350C | Missense Mutation (SNP) | VAF 53/431 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1251838491, COSV100704333; called by muse, mutect2, varscan2
- CACNA1H | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 109/433 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs119454948, CM032203; ClinVar: risk factor; called by muse, mutect2, varscan2
- CACNA2D1 | c.2038C>T p.L680F (on ENST00000356253 / NM_001366867.1; = p.L668F on NM_000722.4) | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV62393667; called by muse, mutect2, varscan2
- CACNA2D1 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62381027; called by muse, mutect2, varscan2
- CACNA2D2 | c.1216C>G p.R406G | Missense Mutation (SNP) | VAF 101/395 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1354929205, COSV99817488; called by muse, mutect2, varscan2
- CACNA2D2 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 86/280 reads (31%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.994); catalogued as rs775944051, COSV99818592; ClinVar: uncertain significance; called by muse, varscan2
- CACNA2D3 | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 77/340 reads (23%) | catalogued as rs764015697, COSV55529480; called by muse, mutect2, varscan2
- CACNG3 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 85/377 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770078893, COSV50068830; called by muse, mutect2, varscan2
- CACNG7 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 82/443 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV99711884; called by muse, mutect2, varscan2
- CADM3 | c.245G>A p.R82Q (on ENST00000368125 / NM_001127173.3; = p.R116Q on NM_021189.5) | Missense Mutation (SNP) | VAF 80/264 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63684047, COSV63685846; called by muse, mutect2, varscan2
- CADPS | c.3555C>T p.F1185= | Splice Region (SNP) | VAF 64/260 reads (25%) | catalogued as rs770554516, COSV51894992; called by muse, mutect2, varscan2
- CADPS2 | c.2869G>A p.E957K | Missense Mutation (SNP) | VAF 94/361 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV57356255, COSV57380759; called by muse, mutect2, varscan2
- CALY | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 126/461 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.381); catalogued as rs143428471, COSV99428690; called by muse, mutect2, varscan2
- CAPRIN1 | c.1822C>G p.R608G | Missense Mutation (SNP) | VAF 110/328 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58220600; called by muse, mutect2, varscan2
- CAPS2 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 101/254 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60826809; called by muse, mutect2, varscan2
- CAPSL | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 53/434 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV68438370; called by muse, varscan2
- CASP5 | c.61A>C p.I21L | Missense Mutation (SNP) | VAF 83/353 reads (24%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV52831167, COSV99507676; called by muse, mutect2, varscan2
- CASR | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 129/474 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.234); catalogued as COSV56137268; called by muse, mutect2, varscan2
- CATSPER4 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 104/576 reads (18%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs774264488, COSV58794628; called by muse, mutect2, varscan2
- CATSPERB | c.2825C>T p.P942L | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT tolerated (0.87); PolyPhen benign (0.189); catalogued as rs1409577085; called by muse, varscan2
- CATSPERB | c.2773G>A p.D925N | Missense Mutation (SNP) | VAF 42/379 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV56425368, COSV99831242; called by muse, mutect2, varscan2
- CATSPERB | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56422654; called by muse, mutect2, varscan2
- CATSPERG | c.2488G>A p.D830N | Missense Mutation (SNP) | VAF 87/311 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53046180; called by muse, mutect2, varscan2
- CBL | c.1238G>A p.G413D | Missense Mutation (SNP) | VAF 85/330 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV50630420; called by muse, mutect2, varscan2
- CBWD5 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1425181264; called by muse, mutect2, varscan2
- CBX6 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 171/676 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs745679342; called by muse, mutect2, varscan2
- CCAR1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 69/277 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.354); catalogued as COSV56269920; called by muse, mutect2, varscan2
- CCBE1 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 130/348 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as rs745953205, COSV67950751; called by muse, mutect2, varscan2
- CCDC105 | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 80/432 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs568010037; called by muse, mutect2, varscan2
- CCDC136 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 103/443 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.475); catalogued as COSV99923176; called by muse, mutect2, varscan2
- CCDC141 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as rs1340252830; called by muse, mutect2, varscan2
- CCDC150 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 39/365 reads (11%) | catalogued as rs200403800; called by muse, mutect2, varscan2
- CCDC152 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 122/300 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62792327; called by muse, mutect2, varscan2
- CCDC168 | c.20155G>A p.E6719K | Missense Mutation (SNP) | VAF 58/323 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.173); catalogued as COSV104400428; called by muse, mutect2, varscan2
- CCDC168 | c.18761G>A p.R6254K | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0.031); catalogued as rs1402803878; called by muse, mutect2, varscan2
- CCDC171 | c.3896C>T p.T1299I | Missense Mutation (SNP) | VAF 95/271 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs752151892; called by muse, mutect2, varscan2
- CCDC173 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 190/387 reads (49%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs768289593, COSV104434540; called by muse, mutect2, varscan2
- CCDC181 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.385); catalogued as rs781751281; called by muse, mutect2, varscan2
- CCDC27 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 94/290 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.356); catalogued as rs758206536; called by muse, mutect2, varscan2
- CCDC27 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 85/534 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53901097; called by muse, mutect2, varscan2
- CCDC28B | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 114/606 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.238); catalogued as rs371310338; called by muse, mutect2, varscan2
- CCDC40 | c.2804C>T p.A935V | Missense Mutation (SNP) | VAF 127/370 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV66474219; called by muse, varscan2
- CCDC63 | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 46/410 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs1327929142; called by muse, mutect2, varscan2
- CCDC69 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 48/358 reads (13%) | catalogued as rs114476897; called by muse, varscan2
- CCDC81 | c.571G>A p.D191N (on ENST00000445632 / NM_001156474.2; = p.D101N on NM_021827.4) | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757599239; called by muse, mutect2, varscan2
- CCDC88A | c.5306C>T p.S1769F (on ENST00000436346 / NM_001365480.1; = p.S1741F on NM_018084.5) | Missense Mutation (SNP) | VAF 144/292 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV55057194; called by muse, mutect2, varscan2
- CCND1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 88/351 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs781047821; called by muse, mutect2, varscan2
- CCNP | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 91/416 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.009); catalogued as rs1415903325; called by muse, mutect2, varscan2
- CCNP | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 91/413 reads (22%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.005); catalogued as rs965298495; called by muse, mutect2, varscan2
- CCNQ | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 123/246 reads (50%) | catalogued as COSV52344997; called by muse, mutect2, varscan2
- CCR8 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 115/477 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs556680323; called by muse, mutect2, varscan2
- CCSER1 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 107/387 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV61458502; called by muse, mutect2, varscan2
- CCSER1 | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.71); catalogued as rs760767540; called by muse, varscan2
- CCT3 | c.493A>G p.I165V | Missense Mutation (SNP) | VAF 76/423 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776248958; called by muse, mutect2, varscan2
- CCT8L2 | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 116/473 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); catalogued as rs773011132; called by muse, mutect2, varscan2
- CD163 | c.1880G>A p.G627E | Missense Mutation (SNP) | VAF 180/562 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765023451, COSV63134443; called by muse, mutect2, varscan2
- CD163L1 | c.2540G>A p.G847E | Missense Mutation (SNP) | VAF 93/319 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV58010794, COSV58025502; called by muse, mutect2, varscan2
- CD163L1 | c.2294C>T p.S765F | Missense Mutation (SNP) | VAF 123/422 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs752812431; called by muse, mutect2, varscan2
- CD180 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 90/330 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99842359; called by muse, mutect2, varscan2
- CD19 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 93/325 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1346128809; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD19 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 150/610 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV61189751; called by muse, mutect2, varscan2
- CD1B | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 53/430 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1425963030, COSV63803782; called by muse, mutect2, varscan2
- CD320 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 53/300 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs746374552; called by muse, mutect2, varscan2
- CD33 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 120/502 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV51801722; called by muse, mutect2, varscan2
- CD33 | c.887G>A p.R296K | Missense Mutation (SNP) | VAF 99/407 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs868629031; called by muse, mutect2, varscan2
- CD5 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 119/520 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV100759814; called by muse, mutect2, varscan2
- CD58 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as rs774492660; called by muse, mutect2, varscan2
- CD79A | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 48/229 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as rs1555844085; called by muse, mutect2, varscan2
- CD8B | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 61/530 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as rs768017195; called by muse, mutect2, varscan2
- CDC14A | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as rs745504275, COSV60556357; called by muse, mutect2, varscan2
- CDC42BPA | c.2579G>A p.R860Q | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as rs774836509, COSV100504712; called by muse, mutect2, varscan2
- CDH10 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 67/397 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV100051700; called by muse, mutect2, varscan2
- CDH13 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 63/242 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs867078223; called by muse, mutect2, varscan2
- CDH15 | c.2210A>G p.Y737C | Missense Mutation (SNP) | VAF 109/417 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759569138; called by muse, mutect2, varscan2
- CDH20 | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 73/295 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV53007677; called by muse, mutect2, varscan2
- CDH24 | c.2455C>T p.P819S | Missense Mutation (SNP) | VAF 36/266 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as rs1317585731; called by muse, varscan2
- CDH4 | c.991T>C p.F331L | Missense Mutation (SNP) | VAF 119/532 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1265692798; called by muse, mutect2, varscan2
- CDHR2 | c.3080C>T p.S1027F | Missense Mutation (SNP) | VAF 116/470 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV56136628; called by muse, mutect2, varscan2
- CDHR4 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 137/457 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs752949287; called by muse, mutect2, varscan2
- CDHR5 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 119/341 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.546); catalogued as COSV57646057; called by muse, mutect2, varscan2
- CDK13 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 123/370 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs1007263035, COSV99077091; called by muse, mutect2, varscan2
- CDK16 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 106/217 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV99331689; called by muse, mutect2, varscan2
- CDK8 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV101037736; called by muse, mutect2, varscan2
- CDR1 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 139/278 reads (50%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV65164357; called by muse, mutect2, varscan2
- CDSN | c.27G>A p.M9I | Missense Mutation (SNP) | VAF 110/574 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV52544953; called by muse, varscan2
- CEACAM5 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.479); catalogued as rs782643301, COSV55753116; called by muse, mutect2, varscan2
- CEACAM8 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs146875157, COSV54990636; called by muse, mutect2, varscan2
- CECR2 | c.1726C>T p.R576C (on ENST00000342247 / NM_001290047.2; = p.R393C on NM_001290046.1) | Missense Mutation (SNP) | VAF 114/500 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs755804225; called by muse, mutect2, varscan2
- CECR2 | c.3730G>A p.G1244R (on ENST00000342247 / NM_001290047.2; = p.G1060R on NM_001290046.1) | Missense Mutation (SNP) | VAF 128/490 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs763080661, COSV52847705; called by muse, mutect2, varscan2
- CECR2 | c.3992C>T p.S1331L (on ENST00000342247 / NM_001290047.2; = p.S1147L on NM_001290046.1) | Missense Mutation (SNP) | VAF 102/439 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as COSV99377856; called by muse, mutect2, varscan2
- CELA3B | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 70/590 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1231345290, COSV100448843; called by muse, mutect2, varscan2
- CEMIP2 | c.1443G>A p.M481I | Missense Mutation (SNP) | VAF 111/439 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs1261036974; called by muse, mutect2, varscan2
- CEMIP2 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 89/303 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV65487494; called by muse, varscan2
- CENPE | c.5075G>A p.R1692K | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.119); catalogued as rs1174924532; called by muse, mutect2, varscan2
- CENPT | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 168/543 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs755385985; called by muse, mutect2, varscan2
- CENPV | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 118/320 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as rs904865995; called by muse, mutect2, varscan2
- CEP126 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.22); catalogued as COSV54830433; called by muse, mutect2, varscan2
- CEP162 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs374584686; called by muse, mutect2, varscan2
- CEP250 | c.3631C>T p.P1211S | Missense Mutation (SNP) | VAF 88/417 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV100699083; called by muse, mutect2, varscan2
- CEP250 | c.3632C>T p.P1211L | Missense Mutation (SNP) | VAF 86/412 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.55); catalogued as rs780050066, COSV61168041; called by muse, mutect2, varscan2
- CEP350 | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 88/279 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1048464410, COSV62602694; called by muse, mutect2, varscan2
- CEP72 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 59/706 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.109); catalogued as rs778694565, COSV53797232; called by muse, mutect2
- CEP78 | c.1849C>T p.P617S (on ENST00000424347 / NM_001349840.2; = p.P618S on NM_032171.3) | Missense Mutation (SNP) | VAF 73/318 reads (23%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.01); catalogued as rs775246597; called by muse, mutect2, varscan2
- CFAP206 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 72/293 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as rs772154736; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.712); catalogued as COSV55828580; called by muse, mutect2, varscan2
- CFAP44 | c.3416G>A p.R1139Q | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1345977528, COSV67248485; called by muse, mutect2, varscan2
- CFAP47 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 95/178 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs1196532368; called by muse, mutect2, varscan2
- CFAP47 | c.2101C>T p.R701* | Nonsense Mutation (SNP) | VAF 114/249 reads (46%) | catalogued as COSV52893468; called by muse, mutect2, varscan2
- CFAP54 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 103/300 reads (34%) | catalogued as rs746695394; called by muse, mutect2, varscan2
- CFAP54 | c.4452G>A p.M1484I | Missense Mutation (SNP) | VAF 108/315 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs1293532960; called by muse, mutect2, varscan2
- CFAP54 | c.5335A>G p.T1779A | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as rs370483025; called by muse, mutect2, varscan2
- CFAP57 | c.1180G>A p.G394S | Missense Mutation (SNP) | VAF 164/478 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs371546643; called by muse, varscan2
- CFAP61 | c.3457C>T p.H1153Y | Missense Mutation (SNP) | VAF 94/251 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99843726; called by muse, mutect2, varscan2
- CFAP91 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV99847058; called by muse, mutect2, varscan2
- CFAP91 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 60/314 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759926184, COSV56339535; called by muse, mutect2, varscan2
- CFAP94 | c.1515G>A p.W505* (on ENST00000320267 / NM_001352064.2; = p.W511* on NM_018272.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 122/388 reads (31%) | catalogued as rs369224348; called by muse, mutect2, varscan2
- CFAP99 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs775364890; called by muse, mutect2, varscan2
- CFH | c.1160G>A p.R387K | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV62777111; called by muse, mutect2, varscan2
- CFHR1 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 104/204 reads (51%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.951); catalogued as rs1436414721, COSV57626948; called by muse, mutect2, varscan2
- CFHR3 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.302); catalogued as rs200996170; called by muse, mutect2, varscan2
- CFTR | c.4129G>T p.D1377Y | Missense Mutation (SNP) | VAF 64/267 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM950257; called by muse, mutect2, varscan2
- CGREF1 | c.727G>A p.G243R (on ENST00000260595; = p.G260R on NM_006569.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 223/652 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV53152358; called by muse, varscan2
- CHAT | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 68/352 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.038); catalogued as rs546158744; called by muse, mutect2, varscan2
- CHD5 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 109/556 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1160932350, COSV52409971; called by muse, mutect2
- CHDH | c.898A>T p.N300Y | Missense Mutation (SNP) | VAF 104/383 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59458500; called by muse, mutect2, varscan2
- CHL1 | c.917G>A p.G306E (on ENST00000397491 / NM_001253387.1; = p.G322E on NM_006614.4) | Missense Mutation (SNP) | VAF 112/401 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56586497; called by muse, mutect2, varscan2
- CHL1 | c.2214G>A p.M738I (on ENST00000397491 / NM_001253387.1; = p.M754I on NM_006614.4) | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.103); catalogued as COSV99849679; called by muse, mutect2, varscan2
- CHMP4C | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 75/337 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1286901173; called by muse, mutect2, varscan2
- CHMP7 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 105/376 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as rs1034398828; called by muse, mutect2, varscan2
- CHRFAM7A | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 74/399 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV100241577, COSV55397388; called by muse, mutect2, varscan2
- CHRNB3 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 54/436 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374938821, COSV51495324; called by muse, mutect2, varscan2
- CHRNB4 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 146/505 reads (29%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.997); catalogued as rs267604334; called by muse, mutect2, varscan2
- CHRNE | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 143/635 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.23); catalogued as rs757968612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST1 | c.850T>C p.S284P | Missense Mutation (SNP) | VAF 164/437 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV57325904; called by muse, mutect2, varscan2
- CHST15 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 108/428 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs878912191, COSV100655059; called by muse, mutect2, varscan2
- CHST15 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 94/360 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs750910183, COSV60562428; called by muse, mutect2, varscan2
- CHST15 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 100/371 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs199887555, COSV60560141, COSV60560330; called by muse, mutect2, varscan2
- CHSY3 | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as COSV59274179, COSV59286369; called by muse, mutect2, varscan2
- CIC | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 50/362 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1207583278; called by muse, mutect2, varscan2
- CIC | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 49/360 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1463119121; called by muse, mutect2, varscan2
- CIC | c.2189C>T p.S730L | Missense Mutation (SNP) | VAF 79/531 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as rs752503838, COSV50663567; called by muse, mutect2, varscan2
- CKAP5 | c.3028C>T p.R1010C | Missense Mutation (SNP) | VAF 133/438 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780302361; called by muse, mutect2, varscan2
- CLCA4 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 64/436 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV55365990; called by muse, mutect2, varscan2
- CLCN1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 93/388 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58373130; called by muse, mutect2, varscan2
- CLEC16A | c.3031C>T p.P1011S | Missense Mutation (SNP) | VAF 134/551 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV55490227; called by muse, varscan2
- CLEC3A | c.355G>A p.E119K (on ENST00000651443; = p.E110K on NM_005752.6) | Missense Mutation (SNP) | VAF 110/449 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs202038528, COSV55219665, COSV55219802, COSV55220651; called by muse, mutect2, varscan2
- CLEC4E | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55225024; called by muse, mutect2, varscan2
- CLEC4G | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 79/311 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61003394; called by muse, mutect2, varscan2
- CLGN | c.893G>A p.S298N | Missense Mutation (SNP) | VAF 42/351 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs982900411; called by muse, mutect2, varscan2
- CLIP4 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV100191250; called by muse, mutect2, varscan2
- CLSPN | c.2443C>T p.R815* | Nonsense Mutation (SNP) | VAF 91/404 reads (23%) | catalogued as rs894279301, COSV52050423; called by muse, mutect2, varscan2
- CLSPN | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 40/330 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs112460042; called by mutect2, varscan2
- CLSTN2 | c.2848G>A p.D950N | Missense Mutation (SNP) | VAF 84/360 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs1158580783; called by muse, varscan2
- CLTCL1 | c.3974C>T p.S1325F | Missense Mutation (SNP) | VAF 132/467 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54226010; called by muse, mutect2, varscan2
- CMYA5 | c.2222C>T p.S741L | Missense Mutation (SNP) | VAF 122/458 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs551260526, COSV71405134, COSV71406357; called by muse, mutect2, varscan2
- CMYA5 | c.6889G>A p.D2297N | Missense Mutation (SNP) | VAF 39/291 reads (13%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs377265303; called by muse, mutect2, varscan2
- CMYA5 | c.9697G>A p.G3233R | Missense Mutation (SNP) | VAF 62/401 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV71411007; called by muse, mutect2, varscan2
- CNGB1 | c.1790G>A p.S597N | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs752197419; called by muse, mutect2, varscan2
- CNGB3 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 59/321 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs372302139, CM050556; called by muse, mutect2, varscan2
- CNKSR1 | c.1213G>A p.D405N (on ENST00000374253 / NM_001297647.2; = p.D398N on NM_006314.3) | Missense Mutation (SNP) | VAF 95/729 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs762074036, COSV64164187; called by muse, mutect2, varscan2
- CNMD | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.817); catalogued as rs763428455, COSV65033492; called by muse, mutect2, varscan2
- CNR2 | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 56/491 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244259465, COSV65693568; called by muse, mutect2, varscan2
- CNTN2 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 77/300 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1476170934; called by muse, mutect2, varscan2
- CNTN3 | c.1919C>T p.S640F | Missense Mutation (SNP) | VAF 80/328 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV55162661; called by muse, varscan2
- CNTN6 | c.3058C>T p.H1020Y | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100610392; called by muse, mutect2, varscan2
- CNTNAP2 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 53/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62216781; called by muse, mutect2, varscan2
- CNTNAP2 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 116/400 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as rs368905425, COSV62202275; called by muse, mutect2, varscan2
- CNTNAP2 | c.2171G>A p.G724E | Missense Mutation (SNP) | VAF 123/456 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.38); catalogued as COSV100668233, COSV62215270; called by muse, mutect2, varscan2
- CNTNAP2 | c.3482G>A p.G1161E | Missense Mutation (SNP) | VAF 86/339 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.656); catalogued as COSV62179159; called by muse, mutect2, varscan2
- CNTNAP2 | c.3899G>A p.G1300E | Missense Mutation (SNP) | VAF 185/729 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.346); catalogued as COSV100672883; called by muse, mutect2, varscan2
- COBL | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 136/431 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV54354106; called by muse, mutect2, varscan2
- COG1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 190/558 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100245233, COSV100245477; called by muse, varscan2
- COG3 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747042102, COSV63071192; called by muse, mutect2, varscan2
- COG7 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 102/387 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV56152096; called by muse, mutect2, varscan2
- COL11A1 | c.4115G>A p.G1372E | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV62197009; called by muse, mutect2, varscan2
- COL11A2 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 176/768 reads (23%) | catalogued as COSV100554068; called by muse, varscan2
- COL12A1 | c.4651G>A p.D1551N | Missense Mutation (SNP) | VAF 89/337 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.71); catalogued as rs76453279; called by muse, mutect2, varscan2
- COL13A1 | c.1652G>A p.G551E (on ENST00000398978 / NM_001130103.2; = p.G532E on NM_080800.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/334 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62566694; called by muse, mutect2, varscan2
- COL14A1 | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 95/346 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as COSV52859528; called by muse, mutect2, varscan2
- COL14A1 | c.4979G>A p.G1660E | Missense Mutation (SNP) | VAF 150/486 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52855995; called by muse, mutect2, varscan2
- COL14A1 | c.5381C>T p.P1794L | Missense Mutation (SNP) | VAF 72/346 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV99918212; called by muse, mutect2, varscan2
- COL15A1 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 117/518 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1373245599; called by muse, mutect2, varscan2
- COL15A1 | c.2684C>T p.P895L | Missense Mutation (SNP) | VAF 108/374 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768401058; called by muse, mutect2, varscan2
- COL18A1 | c.1873G>A p.G625R (on ENST00000359759 / NM_130444.3; = p.G390R on NM_030582.4) | Missense Mutation (SNP) | VAF 60/350 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as rs1281408625; called by muse, mutect2, varscan2
- COL19A1 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV100505375; called by muse, mutect2, varscan2
- COL19A1 | c.3361G>A p.G1121R | Missense Mutation (SNP) | VAF 91/301 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59576433; called by muse, mutect2, varscan2
- COL1A1 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 145/501 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV56802815; called by muse, varscan2
- COL1A2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 71/318 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV51957846; called by muse, mutect2, varscan2
- COL21A1 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.023); catalogued as rs867948640, COSV55159384; called by muse, mutect2, varscan2
- COL22A1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 170/578 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as rs1159707370; called by muse, varscan2
- COL22A1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 67/309 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753523862, COSV57333838; called by muse, varscan2
- COL24A1 | c.2832G>A p.K944= | Splice Region (SNP) | VAF 58/272 reads (21%) | catalogued as rs532411040; called by muse, mutect2, varscan2
- COL24A1 | c.2104G>A p.G702S | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758878506; called by muse, mutect2, varscan2
- COL25A1 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 187/555 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs764703012; called by muse, mutect2, varscan2
- COL3A1 | c.1826G>A p.G609E | Missense Mutation (SNP) | VAF 114/283 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58582876; called by muse, mutect2, varscan2
- COL4A1 | c.2143C>T p.R715C | Missense Mutation (SNP) | VAF 80/374 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs867967840, COSV65424944; called by muse, mutect2, varscan2
- COL4A1 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 122/494 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.301); catalogued as COSV65431214; called by muse, mutect2, varscan2
- COL4A3 | c.2639G>A p.G880E | Missense Mutation (SNP) | VAF 139/315 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67415417; called by muse, mutect2, varscan2
- COL4A4 | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 159/301 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064796418, CM1414118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.452); catalogued as rs369126350; ClinVar: uncertain significance; called by muse, varscan2
- COL5A1 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 119/499 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs761770226, COSV65666859; called by muse, mutect2, varscan2
- COL5A1 | c.3098G>A p.G1033E | Missense Mutation (SNP) | VAF 122/473 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65674595; called by muse, mutect2, varscan2
- COL6A3 | c.2378C>T p.P793L | Missense Mutation (SNP) | VAF 257/534 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs747957874; called by muse, mutect2, varscan2
- COL6A5 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758781062, COSV55213950; called by muse, mutect2, varscan2
- COL6A5 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 83/330 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs374953464; called by muse, varscan2
- COL6A5 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 82/336 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.765); catalogued as rs548996198; called by muse, varscan2
- COL6A5 | c.5084G>A p.G1695E | Missense Mutation (SNP) | VAF 77/279 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485213057, COSV55213734; called by muse, mutect2, varscan2
- COL6A6 | c.4391G>A p.G1464E | Missense Mutation (SNP) | VAF 73/357 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62025516; called by muse, mutect2, varscan2
- COL7A1 | c.7657C>T p.R2553W | Missense Mutation (SNP) | VAF 104/384 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs752294739, COSV60401897; called by muse, mutect2, varscan2
- COL9A2 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 90/392 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1413933689; called by muse, mutect2, varscan2
- CORO1B | c.1068G>A p.S356= | Splice Region (SNP) | VAF 102/286 reads (36%) | catalogued as rs771481040; called by muse, mutect2, varscan2
- CP | c.2576G>A p.W859* | Nonsense Mutation (SNP) | VAF 68/241 reads (28%) | catalogued as rs1338118501; called by muse, mutect2, varscan2
- CPD | c.2962C>T p.R988C | Missense Mutation (SNP) | VAF 120/413 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs760977698, COSV56711796; called by muse, mutect2, varscan2
- CPE | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 48/384 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs930002485; called by muse, mutect2, varscan2
- CPT1C | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 72/311 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1419427462, COSV54918898; called by muse, mutect2, varscan2
- CPZ | c.968G>A p.R323Q (on ENST00000360986 / NM_001014447.3; = p.R312Q on NM_003652.3) | Missense Mutation (SNP) | VAF 148/501 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs538634471, COSV59921979; called by muse, mutect2, varscan2
- CR1 | c.3529C>T p.R1177C | Missense Mutation (SNP) | VAF 132/492 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.804); catalogued as rs769416269; called by muse, mutect2, varscan2
- CR1 | c.4033G>A p.E1345K | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.375); catalogued as COSV100887649; called by muse, mutect2, varscan2
- CR1L | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 51/391 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs753019981; called by muse, mutect2, varscan2
- CRACDL | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 46/580 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.725); catalogued as rs868683234; called by muse, mutect2
- CREB5 | c.331G>A p.G111R (on ENST00000357727 / NM_182898.4; = p.G104R on NM_004904.3) | Missense Mutation (SNP) | VAF 51/540 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.151); catalogued as COSV63217635; called by muse, mutect2
- CRHR1 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 162/700 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758724600, COSV53275209; called by muse, mutect2, varscan2
- CRISP2 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 95/318 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100189234; called by muse, varscan2
- CROCC | c.3508C>T p.R1170C | Missense Mutation (SNP) | VAF 231/652 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs1367008210; called by muse, mutect2, varscan2
- CROCC | c.4849C>T p.R1617W | Missense Mutation (SNP) | VAF 62/456 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1204545450; called by muse, mutect2, varscan2
- CROCC2 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 51/496 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.463); catalogued as rs1323066736; called by muse, mutect2, varscan2
- CRTAC1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 104/469 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53996929; called by muse, mutect2, varscan2
- CRYBB1 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 142/509 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.382); catalogued as COSV99316133; called by muse, mutect2, varscan2
- CRYBG2 | c.2956G>A p.G986R | Missense Mutation (SNP) | VAF 68/378 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301144293; called by muse, mutect2, varscan2
- CSF1R | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 75/484 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV53843892; called by muse, mutect2, varscan2
- CSF3R | c.2173C>T p.Q725* | Nonsense Mutation (SNP) | VAF 138/577 reads (24%) | catalogued as COSV58963307; called by muse, mutect2, varscan2
- CSMD1 | c.9493G>A p.G3165R (on ENST00000520002; = p.G3164R on NM_033225.6) | Missense Mutation (SNP) | VAF 71/359 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1043070197; called by muse, mutect2, varscan2
- CSMD1 | c.8704G>A p.E2902K (on ENST00000520002; = p.E2901K on NM_033225.6) | Missense Mutation (SNP) | VAF 86/421 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.396); catalogued as COSV59290937; called by muse, mutect2, varscan2
- CSMD1 | c.8024G>A p.R2675Q (on ENST00000520002; = p.R2674Q on NM_033225.6) | Missense Mutation (SNP) | VAF 60/253 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs775089714, COSV100153884, COSV59332663; called by muse, varscan2
- CSMD1 | c.7871G>A p.G2624E (on ENST00000520002; = p.G2623E on NM_033225.6) | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59285778, COSV59287194; called by muse, varscan2
- CSMD1 | c.4964C>T p.S1655F (on ENST00000520002; = p.S1654F on NM_033225.6) | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0.047); catalogued as COSV59350402; called by muse, mutect2, varscan2
- CSMD1 | c.3934G>A p.D1312N (on ENST00000520002; = p.D1311N on NM_033225.6) | Missense Mutation (SNP) | VAF 50/277 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs777606817, COSV59342471; called by muse, mutect2, varscan2
- CSMD1 | c.1864C>T p.R622* (on ENST00000520002; = p.R621* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 148/497 reads (30%) | catalogued as COSV59319061; called by muse, mutect2, varscan2
- CSMD2 | c.4255G>A p.G1419R | Missense Mutation (SNP) | VAF 94/522 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53903397; called by muse, mutect2, varscan2
- CSMD2 | c.3611C>T p.S1204F | Missense Mutation (SNP) | VAF 59/284 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.434); catalogued as rs1433764108, COSV53920008; called by muse, mutect2, varscan2
- CSMD3 | c.4499T>C p.I1500T (on ENST00000297405 / NM_001363185.1; = p.I1396T on NM_052900.3) | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as rs200017659; called by muse, mutect2, varscan2
- CSMD3 | c.206T>C p.L69S | Missense Mutation (SNP) | VAF 64/286 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs746490423; called by muse, mutect2, varscan2
- CSNK1A1L | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 60/362 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV65789464; called by muse, mutect2, varscan2
- CSPP1 | c.836G>A p.R279K (on ENST00000676605; = p.R238K on NM_024790.6) | Missense Mutation (SNP) | VAF 139/387 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs750660079; called by muse, mutect2, varscan2
- CSTA | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 69/280 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV52611830; called by muse, mutect2, varscan2
- CTSZ | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 100/410 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1295015531; called by muse, varscan2
- CUX2 | c.3820G>A p.E1274K | Missense Mutation (SNP) | VAF 136/393 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as COSV55632376; called by muse, varscan2
- CWH43 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs771090704, COSV56944501, COSV99893297; called by muse, mutect2
- CXADR | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs372788152, COSV53027863; called by muse, mutect2, varscan2
- CYBRD1 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV58427016; called by muse, mutect2
- CYLC2 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 99/375 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs369079750; called by muse, mutect2, varscan2
- CYP11A1 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 113/445 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs777640411, COSV51434677; called by muse, mutect2, varscan2
- CYP17A1 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 77/303 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as rs267602347, COSV64004940; called by muse, mutect2, varscan2
- CYP21A2 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 89/452 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs772317717, CM066040; called by muse, mutect2, varscan2
- CYP21A2 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 82/429 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); catalogued as rs1358140657; called by muse, mutect2, varscan2
- CYP26B1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 268/586 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs955332130; called by muse, mutect2, varscan2
- CYP2C19 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as rs866704734, COSV64907162; called by muse, mutect2, varscan2
- CYP2C8 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 87/360 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as COSV100987989; called by muse, mutect2, varscan2
- CYP2D6 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 116/1037 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs67780109; called by muse, mutect2, varscan2
- CYP3A43 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749902724, COSV55936149; called by muse, mutect2, varscan2
- CYP3A5 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 82/341 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV56119858; called by muse, mutect2, varscan2
- CYP4A11 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 83/478 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs370892962, COSV60224540; called by muse, mutect2, varscan2
- CYP4A22 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 74/320 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.192); catalogued as rs373881337; called by muse, mutect2, varscan2
- CYP4A22 | c.809G>A p.R270K | Missense Mutation (SNP) | VAF 88/373 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs768203901, COSV53742922; called by muse, mutect2, varscan2
- CYP4B1 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 92/466 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as rs942315525, COSV54722033; called by muse, mutect2, varscan2
- CYP4B1 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.519); catalogued as rs781064413, COSV54722729; called by muse, mutect2, varscan2
- CYP4F12 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs763786060, COSV61173292; called by muse, mutect2, varscan2
- CYP4F12 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs375001752; called by muse, mutect2, varscan2
- CYP4F8 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as rs773731200, COSV57854178; called by muse, mutect2, varscan2
- DAB1 | c.1348G>A p.D450N (on ENST00000371231; = p.D417N on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 118/527 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.859); catalogued as COSV64690418; called by muse, varscan2
- DAG1 | c.2474C>T p.P825L | Missense Mutation (SNP) | VAF 113/512 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58185520; called by muse, mutect2, varscan2
- DAGLA | c.1545C>G p.F515L | Missense Mutation (SNP) | VAF 116/420 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV57195367; called by muse, mutect2, varscan2
- DBH | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 75/334 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55040152; called by muse, mutect2, varscan2
- DCAF12L1 | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 180/375 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV64422833; called by muse, mutect2, varscan2
- DCAF13 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 101/377 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.148); catalogued as COSV99885600; called by muse, mutect2, varscan2
- DCAF4L2 | c.1126C>G p.R376G | Missense Mutation (SNP) | VAF 142/427 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV60481489; called by muse, mutect2, varscan2
- DCAF8L1 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 135/273 reads (49%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.074); catalogued as COSV71595141, COSV71595142; called by muse, varscan2
- DCDC1 | c.2213G>A p.G738E | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs751269799; called by muse, mutect2, varscan2
- DCDC2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 94/455 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99219658; called by muse, mutect2, varscan2
- DCST2 | c.1232A>G p.N411S | Missense Mutation (SNP) | VAF 41/318 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs576979808; called by muse, mutect2, varscan2
- DDX27 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 90/334 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs267605978, COSV65610710; called by muse, mutect2, varscan2
- DDX4 | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 60/412 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV61755820; called by muse, mutect2, varscan2
- DDX50 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 97/437 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99056837; called by muse, mutect2, varscan2
- DEFA5 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 139/714 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.652); catalogued as COSV57962415; called by muse, mutect2, varscan2
- DEFB1 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 128/513 reads (25%) | catalogued as rs148577927; called by muse, mutect2, varscan2
- DENND2D | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 70/288 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV100718542; called by muse, mutect2, varscan2
- DENND5B | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60901928; called by muse, mutect2, varscan2
- DEPDC1B | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 75/407 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs202011984, COSV54013109; called by muse, mutect2, varscan2
- DEPDC5 | c.3263C>T p.S1088L (on ENST00000400246; = p.S1157L on NM_014662.5) | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as rs376487148, COSV99836702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DEPDC7 | c.1246C>T p.Q416* (on ENST00000241051 / NM_001077242.2; = p.Q407* on NM_139160.2) | Nonsense Mutation (SNP) | VAF 41/157 reads (26%) | catalogued as COSV53806557; called by muse, mutect2, varscan2
- DFFB | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 88/467 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs765633248; called by muse, mutect2, varscan2
- DHDH | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 90/482 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs761438992, COSV55482416; called by muse, mutect2, varscan2
- DHRS7C | c.833C>T p.P278L (on ENST00000330255 / NM_001220493.2; = p.P277L on NM_001105571.3) | Missense Mutation (SNP) | VAF 206/515 reads (40%) | SIFT tolerated (1); PolyPhen possibly damaging (0.88); catalogued as COSV57651478; called by muse, mutect2, varscan2
- DHX57 | c.3974C>T p.S1325F | Missense Mutation (SNP) | VAF 182/442 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV54892303; called by muse, varscan2
- DHX57 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 155/399 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as COSV54890949; called by muse, mutect2, varscan2
- DIO3 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 107/411 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV63773322; called by muse, mutect2, varscan2
- DIPK1C | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 142/388 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100679966; called by muse, mutect2, varscan2
- DISP3 | c.2489C>T p.T830I | Missense Mutation (SNP) | VAF 82/350 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1205568999; called by muse, mutect2, varscan2
- DISP3 | c.3637C>T p.L1213F | Missense Mutation (SNP) | VAF 103/432 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.636); catalogued as rs1299169094; called by muse, mutect2, varscan2
- DKK4 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 119/530 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.081); catalogued as rs772507402, COSV55182146; called by muse, mutect2, varscan2
- DLAT | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 90/400 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as rs782667970; called by muse, mutect2, varscan2
- DLG2 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 64/294 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs143052833, COSV54617818; called by muse, mutect2, varscan2
- DLG2 | c.217G>A p.E73K (on ENST00000650630 / NM_001351274.2; = p.E36K on NM_001142699.3) | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.839); catalogued as COSV65825365; called by muse, mutect2, varscan2
- DLGAP2 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 120/625 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70102618; called by muse, mutect2, varscan2
- DLX2 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 57/541 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs760753513; called by muse, mutect2, varscan2
- DMBT1 | c.5372G>A p.G1791E (on ENST00000338354 / NM_001377530.1; = p.G1034E on NM_004406.3) | Missense Mutation (SNP) | VAF 142/577 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57544738; called by muse, mutect2, varscan2
- DMXL1 | c.3551C>T p.P1184L | Missense Mutation (SNP) | VAF 80/361 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs1561724957, COSV100224393; called by muse, mutect2, varscan2
- DNA2 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 66/312 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.054); catalogued as rs267602555; called by muse, mutect2, varscan2
- DNAH1 | c.7234C>T p.L2412F | Missense Mutation (SNP) | VAF 102/358 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.107); catalogued as COSV70237828; called by muse, varscan2
- DNAH10 | c.9976G>A p.E3326K (on ENST00000409039; = p.E3265K on NM_207437.3) | Missense Mutation (SNP) | VAF 161/355 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs867138131; called by muse, mutect2, varscan2
- DNAH10 | c.11527G>A p.E3843K (on ENST00000409039; = p.E3782K on NM_207437.3) | Missense Mutation (SNP) | VAF 58/495 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV68999230; called by muse, mutect2, varscan2
- DNAH10 | c.12410C>T p.P4137L (on ENST00000409039; = p.P4076L on NM_207437.3) | Missense Mutation (SNP) | VAF 150/415 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764098693, COSV101292169; called by muse, mutect2, varscan2
- DNAH11 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV60942355; called by muse, mutect2, varscan2
- DNAH11 | c.7529G>A p.G2510E | Missense Mutation (SNP) | VAF 217/473 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60945355; called by muse, mutect2, varscan2
- DNAH12 | c.5917C>T p.Q1973* (on ENST00000351747; = p.Q1992* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 73/296 reads (25%) | catalogued as rs1281491609; called by muse, mutect2, varscan2
- DNAH14 | c.5563G>A p.D1855N (on ENST00000445597; = p.D2276N on NM_001367479.1) | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs1313116202, COSV59896279; called by muse, mutect2, varscan2
- DNAH14 | c.6772C>T p.R2258C (on ENST00000445597; = p.R2911C on NM_001367479.1) | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs770222940; called by muse, mutect2, varscan2
- DNAH17 | c.9507G>A p.M3169I | Missense Mutation (SNP) | VAF 154/510 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV67757530; called by muse, mutect2, varscan2
- DNAH17 | c.4567A>G p.I1523V | Missense Mutation (SNP) | VAF 151/401 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as rs1321453972, COSV101101090; called by muse, mutect2, varscan2
- DNAH17 | c.3175C>T p.H1059Y | Missense Mutation (SNP) | VAF 102/463 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as rs1030104038, COSV67760706; called by muse, mutect2, varscan2
- DNAH17 | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 68/280 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1022064145; called by muse, mutect2, varscan2
- DNAH17 | c.1685T>C p.L562S | Missense Mutation (SNP) | VAF 122/342 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.481); catalogued as COSV67752443; called by muse, varscan2
- DNAH17 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as rs780914196; called by muse, varscan2
- DNAH2 | c.8654A>G p.N2885S | Missense Mutation (SNP) | VAF 188/429 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as rs970256099; called by muse, mutect2, varscan2
- DNAH3 | c.9709G>A p.E3237K | Missense Mutation (SNP) | VAF 135/520 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV54512537; called by muse, mutect2, varscan2
- DNAH3 | c.8263G>A p.E2755K | Missense Mutation (SNP) | VAF 76/295 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs759835468, COSV54509344; called by muse, mutect2, varscan2
- DNAH5 | c.13492G>A p.E4498K | Missense Mutation (SNP) | VAF 140/383 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54204981; called by muse, mutect2, varscan2
- DNAH5 | c.12437C>T p.S4146F | Missense Mutation (SNP) | VAF 234/616 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs750170721; called by muse, mutect2, varscan2
- DNAH5 | c.11275G>A p.E3759K | Missense Mutation (SNP) | VAF 38/599 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1349417589, COSV54243331; called by muse, mutect2
- DNAH5 | c.10912G>A p.E3638K | Missense Mutation (SNP) | VAF 48/628 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs267600359, COSV99451038; called by muse, mutect2
- DNAH5 | c.10282G>A p.A3428T | Missense Mutation (SNP) | VAF 65/367 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as rs760220268; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.9151G>A p.D3051N | Missense Mutation (SNP) | VAF 60/608 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs1171709721; called by muse, mutect2
- DNAH5 | c.6149C>T p.S2050F | Missense Mutation (SNP) | VAF 164/492 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs865859969, COSV54207857; called by muse, varscan2
- DNAH5 | c.4951G>A p.E1651K | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54251553; called by muse, mutect2, varscan2
- DNAH5 | c.4291G>A p.D1431N | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as COSV54239209; called by muse, mutect2, varscan2
- DNAH5 | c.3520C>T p.L1174F | Missense Mutation (SNP) | VAF 225/613 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.257); catalogued as COSV54215029; called by muse, mutect2, varscan2
- DNAH5 | c.2956C>T p.H986Y | Missense Mutation (SNP) | VAF 68/364 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99451043; called by muse, varscan2
- DNAH5 | c.2908C>T p.L970F | Missense Mutation (SNP) | VAF 176/512 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as rs1336360020, COSV54238228; called by muse, mutect2, varscan2
- DNAH5 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 296/538 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54212875; called by muse, mutect2, varscan2
- DNAH5 | c.1417T>C p.F473L | Missense Mutation (SNP) | VAF 42/511 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.327); catalogued as rs1162532498; called by muse, mutect2
- DNAH5 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 64/533 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as rs866784113, COSV54205135; called by muse, mutect2, varscan2
- DNAH7 | c.9133C>T p.P3045S | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as rs1371302173; called by muse, mutect2, varscan2
- DNAH8 | c.12191G>A p.R4064Q | Missense Mutation (SNP) | VAF 68/291 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327466194, COSV59421605; called by muse, mutect2, varscan2
- DNAH8 | c.12986G>A p.R4329K | Missense Mutation (SNP) | VAF 87/351 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59435605, COSV59460628; called by muse, mutect2, varscan2
- DNAH9 | c.2891C>T p.P964L | Missense Mutation (SNP) | VAF 157/335 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV52363552; called by muse, mutect2, varscan2
- DOCK1 | c.5540C>T p.P1847L | Missense Mutation (SNP) | VAF 73/401 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.981); catalogued as rs868636153; called by muse, mutect2
- DOCK2 | c.3925G>A p.E1309K | Missense Mutation (SNP) | VAF 208/380 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs146643993; called by muse, varscan2
- DOCK3 | c.4424G>A p.W1475* | Nonsense Mutation (SNP) | VAF 62/262 reads (24%) | catalogued as COSV56526303; called by muse, varscan2
- DOCK4 | c.5174C>T p.A1725V | Missense Mutation (SNP) | VAF 88/406 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV70233732; called by muse, varscan2
- DOCK4 | c.3647T>G p.F1216C | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV69855222; called by muse, mutect2, varscan2
- DOK5 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 75/340 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV52827278; called by muse, mutect2, varscan2
- DOK5 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 66/283 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as rs375799502; called by muse, mutect2, varscan2
- DOLPP1 | c.362G>A p.R121K | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs886151898, COSV59910410; called by muse, mutect2, varscan2
- DOP1B | c.4876C>T p.R1626* | Nonsense Mutation (SNP) | VAF 76/430 reads (18%) | catalogued as rs373514422, COSV67694472; called by muse, mutect2, varscan2
- DOT1L | c.3436C>T p.P1146S | Missense Mutation (SNP) | VAF 75/443 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101288849, COSV67110574; called by muse, mutect2, varscan2
- DPP10 | c.1896-1G>A p.X632_splice | Splice Site (SNP) | VAF 92/234 reads (39%) | catalogued as COSV59662501; called by muse, varscan2
- DPYD | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); catalogued as COSV64595363, COSV64598327; called by muse, mutect2, varscan2
- DPYSL5 | c.1523G>A p.G508E | Missense Mutation (SNP) | VAF 63/555 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.131); catalogued as COSV56512213; called by muse, mutect2, varscan2
- DSCAM | c.4171A>G p.T1391A | Missense Mutation (SNP) | VAF 46/350 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1293311951; called by muse, mutect2, varscan2
- DSCAM | c.2950C>T p.P984S | Missense Mutation (SNP) | VAF 80/289 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV68025372; called by muse, mutect2, varscan2
- DSCAM | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 117/451 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs369222297, COSV68036796; called by muse, mutect2, varscan2
- DSG1 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 39/124 reads (31%) | catalogued as rs145081747, CM086709; called by muse, mutect2, varscan2
- DSP | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 41/348 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV65796367; called by muse, mutect2, varscan2
- DTL | c.1027A>G p.I343V | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as rs140344470; called by muse, mutect2, varscan2
- DTWD2 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 68/390 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100406941; called by muse, mutect2, varscan2
- DUSP22 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 72/779 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as rs1460729199; called by muse, mutect2
- DUSP26 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 117/489 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV56360640; called by muse, mutect2, varscan2
- DUXB | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs961946328; called by muse, mutect2, varscan2
- DYRK1B | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 113/435 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.276); catalogued as rs1315990800; called by muse, mutect2, varscan2
- DYSF | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs184771575, COSV50303935; called by muse, varscan2
- DZIP3 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.674); catalogued as rs780109183, COSV64311041, COSV64311670; called by muse, mutect2, varscan2
- E4F1 | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 108/436 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57038514; called by muse, mutect2, varscan2
- EBF2 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 88/434 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68776205; called by muse, mutect2, varscan2
- EBF2 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 88/430 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68779664; called by muse, mutect2, varscan2
- ECT2L | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746071732; called by muse, mutect2, varscan2
- EDA2R | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 134/272 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs867588990, COSV53630915; called by muse, mutect2, varscan2
- EDIL3 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 58/266 reads (22%) | catalogued as COSV99677396; called by muse, mutect2, varscan2
- EDN3 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 158/632 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs457651, COSV61109378; called by muse, varscan2
- EEF1AKMT3 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 241/604 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.828); catalogued as rs1391351492; called by muse, mutect2, varscan2
- EFCAB1 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 104/332 reads (31%) | catalogued as rs751867551; called by muse, mutect2, varscan2
- EFCAB8 | c.2621G>A p.G874E | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145443519; called by muse, mutect2, varscan2
- EFL1 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1401834310; called by muse, mutect2, varscan2
- EGFLAM | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 161/461 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59303774; called by muse, mutect2, varscan2
- EGFLAM | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 146/475 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV59302449; called by muse, varscan2
- EHHADH | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 96/347 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.484); catalogued as COSV51632071; called by muse, mutect2, varscan2
- EIF2B2 | c.694-1G>A p.X232_splice | Splice Site (SNP) | VAF 95/300 reads (32%) | catalogued as rs1286508111; called by muse, mutect2, varscan2
- EIF2S3B | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 98/569 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV59373256; called by muse, mutect2, varscan2
- EIF2S3B | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 99/564 reads (18%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as rs745800418; called by muse, mutect2, varscan2
- EIF4E2 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 147/298 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1039939878; called by muse, mutect2, varscan2
- EIF4G3 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 96/474 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1399708241; called by muse, varscan2
- ELAVL2 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as rs867331367, COSV56356901; called by muse, mutect2, varscan2
- ELAVL4 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 96/368 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63917669; called by muse, mutect2, varscan2
- ELF1 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.532); catalogued as rs147878914; called by muse, mutect2, varscan2
- ELF2 | c.1564C>T p.P522S (on ENST00000379550 / NM_001331036.2; = p.P462S on NM_006874.4) | Missense Mutation (SNP) | VAF 263/521 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1488457619, COSV55492331; called by muse, mutect2, varscan2
- ELFN2 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 152/568 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as rs773900601; called by muse, mutect2, varscan2
- ELOVL3 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 105/456 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV64175102; called by muse, mutect2, varscan2
- EMID1 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 144/535 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1291636661; called by muse, mutect2, varscan2
- EMILIN2 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 117/283 reads (41%) | catalogued as rs1256513191; called by muse, mutect2, varscan2
- ENG | c.1568G>A p.S523N | Missense Mutation (SNP) | VAF 156/646 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.795); catalogued as rs766445175; called by muse, mutect2, varscan2
- ENPP6 | c.1306C>T p.L436F | Missense Mutation (SNP) | VAF 106/308 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs1283686516; called by muse, mutect2, varscan2
- ENPP7 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 180/720 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as rs782676722; called by muse, mutect2, varscan2
- ENTPD1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as rs1324434144; called by muse, mutect2, varscan2
- EOGT | c.1451C>T p.T484I (on ENST00000383701 / NM_001278689.2; = p.T400I on NM_173654.3) | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs1191496361; called by muse, mutect2, varscan2
- EP400 | c.5000C>T p.P1667L | Missense Mutation (SNP) | VAF 54/347 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.242); catalogued as rs752648512; called by muse, mutect2, varscan2
- EPB41L4B | c.2297C>T p.P766L | Missense Mutation (SNP) | VAF 65/323 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63124117; called by muse, mutect2, varscan2
- EPHA10 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 106/591 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV57624622, COSV57624713; called by muse, mutect2, varscan2
- EPHA5 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs372519544, COSV99895849; called by muse, mutect2, varscan2
- EPHA6 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 95/354 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs760704852, COSV67556568; called by muse, mutect2, varscan2
- EPHA6 | c.2640G>A p.M880I (on ENST00000389672 / NM_001080448.3; = p.M272I on NM_173655.4) | Missense Mutation (SNP) | VAF 82/341 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV67560255; called by muse, mutect2, varscan2
- EPHA7 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65169020; called by muse, mutect2, varscan2
- EPHB1 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 60/279 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV67657391; called by muse, mutect2, varscan2
- EPHB2 | c.1535C>T p.T512I | Missense Mutation (SNP) | VAF 53/487 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs867477730, COSV65862764; called by muse, mutect2, varscan2
- EPHB6 | c.2464C>T p.P822S | Missense Mutation (SNP) | VAF 89/375 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV63893711; called by muse, mutect2, varscan2
- EPN1 | c.919C>T p.P307S (on ENST00000270460 / NM_001321263.1; = p.P282S on NM_013333.3) | Missense Mutation (SNP) | VAF 140/600 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs754269275; called by muse, varscan2
- EPPK1 | c.6644G>A p.R2215H | Missense Mutation (SNP) | VAF 182/786 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as rs191805316, COSV73260956, COSV73261772; called by muse, mutect2, varscan2
- ERBB2 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 227/709 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs561322621; called by muse, mutect2, varscan2
- ERBB4 | c.1261G>A p.V421M | Missense Mutation (SNP) | VAF 158/321 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as COSV53547612; called by muse, mutect2, varscan2
- ERBB4 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 28/379 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV53578575; called by muse, mutect2
- ERG | c.1001C>T p.S334F (on ENST00000398919 / NM_001243428.1; = p.S310F on NM_004449.4) | Missense Mutation (SNP) | VAF 81/306 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV55732462; called by muse, mutect2, varscan2
- ERICH3 | c.3674G>A p.G1225E | Missense Mutation (SNP) | VAF 132/549 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV58610360; called by muse, mutect2, varscan2
- ERP44 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 58/275 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99316813; called by muse, mutect2, varscan2
- ESCO2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767123113, COSV59414087; called by muse, mutect2, varscan2
- ESPL1 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 111/438 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs539894607, COSV57758617; called by muse, mutect2, varscan2
- ESR1 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 70/278 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52786406; called by muse, varscan2
- ESRRB | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs773144277, COSV55060173; called by muse, mutect2, varscan2
- ETV1 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 60/580 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as rs781034658, COSV54145886, COSV99623216; called by muse, mutect2
- ETV1 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 65/370 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.322); catalogued as rs761565850, COSV99622602; called by muse, mutect2, varscan2
- EVI5L | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 75/330 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1279074715, COSV99563537; called by muse, varscan2
- EVPL | c.5854C>T p.R1952C | Missense Mutation (SNP) | VAF 196/595 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376108255; called by muse, mutect2, varscan2
- EVPL | c.5114G>A p.R1705K | Missense Mutation (SNP) | VAF 178/538 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1309403186; called by muse, mutect2, varscan2
- EVPL | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 121/545 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs267605057; called by muse, mutect2, varscan2
- EVPL | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as rs147209597; called by muse, mutect2, varscan2
- EVPL | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 60/308 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.631); catalogued as rs1431119888; called by muse, mutect2, varscan2
- EXD3 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 159/581 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.879); catalogued as rs1564523489; called by muse, mutect2, varscan2
- EXOC3L4 | c.1675C>T p.Q559* | Nonsense Mutation (SNP) | VAF 107/429 reads (25%) | catalogued as rs1024303472; called by muse, mutect2, varscan2
- EXOC3L4 | c.2098C>T p.P700S | Missense Mutation (SNP) | VAF 77/414 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs768494124, COSV66295959; called by muse, mutect2, varscan2
- EYA1 | c.1664G>A p.G555E | Missense Mutation (SNP) | VAF 76/275 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58168335; called by muse, varscan2
- EYA4 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 95/325 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868169482; called by muse, mutect2, varscan2
- EZHIP | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 117/244 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs782039713; called by muse, mutect2, varscan2
- F11 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 88/268 reads (33%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.998); catalogued as COSV53007356; called by muse, mutect2, varscan2
- F11 | c.1718G>A p.G573E | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754109115, CM043486, COSV53002036; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F13B | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.049); catalogued as rs766408940, COSV66373657; called by muse, mutect2, varscan2
- F2 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 128/427 reads (30%) | catalogued as rs1202167691; called by muse, mutect2, varscan2
- F5 | c.6216G>A p.M2072I | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs148045855; called by muse, mutect2, varscan2
- F5 | c.2717C>T p.P906L | Missense Mutation (SNP) | VAF 73/438 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); catalogued as COSV100889098; called by muse, varscan2
- F8 | c.5962G>A p.E1988K | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV100811670; called by muse, mutect2, varscan2
- F8 | c.4198C>T p.P1400S | Missense Mutation (SNP) | VAF 126/253 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1557278482, COSV64272489; called by muse, mutect2, varscan2
- FADS6 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 127/485 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.024); catalogued as rs772148800, COSV59604129; called by muse, mutect2, varscan2
- FAHD2B | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 161/417 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1313202757; called by muse, mutect2, varscan2
- FAIM2 | c.914C>T p.T305I | Missense Mutation (SNP) | VAF 67/289 reads (23%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.697); catalogued as rs1334455485; called by muse, varscan2
- FAIM2 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 131/639 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs748035687; called by muse, mutect2, varscan2
- FAM131C | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 88/740 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV65152768; called by mutect2, varscan2
- FAM131C | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 130/860 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs752539505; called by muse, varscan2
- FAM153A | c.105G>A p.M35I | Missense Mutation (SNP) | VAF 79/335 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.043); catalogued as COSV100646979; called by muse, mutect2, varscan2
- FAM160A1 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 103/336 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.36); catalogued as rs112244723, COSV101475051; called by muse, mutect2, varscan2
- FAM170A | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 94/397 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.264); catalogued as COSV58923993; called by muse, mutect2, varscan2
- FAM170A | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 129/456 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV58924238; called by muse, mutect2, varscan2
- FAM184B | c.2971G>A p.D991N | Missense Mutation (SNP) | VAF 120/394 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs368263511, COSV99401684; called by muse, mutect2, varscan2
- FAM186A | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 85/368 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.33); catalogued as rs900672287; called by muse, mutect2, varscan2
- FAM189A2 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758112107; called by muse, mutect2, varscan2
- FAM47A | c.1709C>T p.S570L | Missense Mutation (SNP) | VAF 96/212 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.073); catalogued as rs1339397781, COSV60497528; called by muse, varscan2
- FAM47A | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 139/243 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as rs1301512208, COSV100649985, COSV60494608; called by muse, mutect2, varscan2
- FAM71E2 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as rs770962978, COSV52772262; called by muse, mutect2, varscan2
- FAM90A1 | c.872A>G p.K291R | Missense Mutation (SNP) | VAF 112/698 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as COSV100274183; called by muse, varscan2
- FANCD2 | c.4402C>T p.P1468S | Missense Mutation (SNP) | VAF 49/325 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs764865805, COSV55036391; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCI | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 120/446 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1281730489, COSV100168302; called by muse, mutect2, varscan2
- FASN | c.4408C>T p.R1470W | Missense Mutation (SNP) | VAF 132/444 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60757301; called by muse, mutect2, varscan2
- FASN | c.2795C>T p.S932F | Missense Mutation (SNP) | VAF 73/342 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs146356200; called by muse, mutect2, varscan2
- FAT1 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 106/350 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1374224550; called by muse, mutect2, varscan2
- FAT3 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as COSV53163808; called by muse, mutect2, varscan2
- FAT3 | c.12641G>A p.G4214D | Missense Mutation (SNP) | VAF 122/412 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.202); catalogued as rs1378994439; called by muse, varscan2
- FAT4 | c.8501C>T p.P2834L | Missense Mutation (SNP) | VAF 44/386 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV58677624, COSV58678467; called by muse, mutect2, varscan2
- FBXL5 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs899990946, COSV100378009; called by muse, mutect2, varscan2
6,758 further variants in this file (4,082 protein-altering or splice-affecting, 2,407 silent, 269 other) are not listed here.
